Somatic mutation profile of tumor specimen 0DR3MF from CCDI case PBCFZS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (546 days).
Specimen 0DR3MF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb8e23dd-2353-48b1-854d-b1f056d2c370.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR3L6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0cd106c-e357-4a3d-ad51-44cc4e7c660c

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Splice Region 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC002094.3 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 28/466 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as rs538721924, COSV52648307; called by muse, mutect2
- TTC23L | c.841-4C>T | Splice Region (SNP) | VAF 14/368 reads (4%) | called by muse, mutect2
- PCDHB15 | c.2253C>T p.Y751= | Silent (SNP) | VAF 10/300 reads (3%) | catalogued as rs376420795; called by muse, mutect2
- RADIL | c.210C>T p.D70= | Silent (SNP) | VAF 10/226 reads (4%) | called by muse, mutect2
